Surgical pathology report (de-identified scan), TCGA case TCGA-36-2538, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2538-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

TCGA - 36 - 2538

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

1. EXTERNAL ABDOMINAL WALL OLD LAPAROSCOPIC PORT TUMOUR NODULE showing a fragment of fibrofatty tissue positive for high-grade papillary serous carcinoma with focal foreign body inflammatory reaction.
2. INTERNAL ABDOMINAL WALL OLD LAPAROSCOPIC PORT TUMOUR NODULE showing a fragment of fibrofatty tissue with adherent muscle positive for high-grade papillary serous carcinoma with focal foreign body inflammatory reaction.
3. Total hysterectomy and left salpingo-oophorectomy:
- A. High-grade (Grade 3 of 3) papillary serous carcinoma involving the surface and the parenchyma of the left ovary (please see comment)
- B. Tumor measures 3 cm in size in the left ovary
- C. Tumor involve in the posterior cul-de-sac region of the uterus
- D. Tumor present in the lumen of the left fallopian tube with no direct parenchymal involvement
- E. No definite lymphovascular invasion identified
- F. Benign secretory endometrium
- G. Unremarkable cervix

[page 2 of 4]
4. BIOPSY OF RIGHT IP LIGAMENT: Fragments of fibrofatty tissue positive for high-grade papillary serous carcinoma.

5. Omentum, omentectomy: Diffuse involvement of the omental fibrofatty tissue by high-grade papillary serous carcinoma.

6. Corresponding peritoneal fluid cytology [REDACTED] positive for carcinoma.

[REDACTED]

Final Diagnosis Comment:

The left ovary shows surface involvement by high-grade papillary serous carcinoma with associated desmoplastic reaction and multiple coalescing cortical nodules of carcinoma, ranging in size from 0.5 to 1 cm, and measuring 3 cm overall. This pattern of involvement together with the overall relative small size of the tumor suggest that this may represent secondary involvement, most likely by the carcinoma arising from the right ovary/fallopian tube based on the provided clinical history (particularly if the tumor present in the right ovary was significantly larger in size with direct tubal involvement).

Clinical History as Provided by Submitting Physician:

Pap serous ovarian CA

S/P (R) oophorectomy - now full staging

- [REDACTED]
- A. External abd. wall old laparoscopic port tumour nodule
- B. Internal abd. wall old laparoscope port tumour nodule
- C. Uterus, cervix, left tube + left ovary
- D. Biopsy of right IP ligament
- E. Omentum

Specimens Received:

- A: external abdomen wall old laparoscopic port tumor nodule
- B: internal abdomen wall old laproscopic port tumor nodule
- C: uterus + cervix + left tube + left ovary
- D: biopsy of right IP ligament

[page 3 of 4]
E: omentum

Gross Description:

The specimen is received in five containers, all labelled with the patient's name and ID.

Container A is labelled EXTERNAL ABDOMINAL WALL OLD LAPAROSCOPIC PORT TUMOUR NODULE and consists of a yellow-tan nodular fragment of tissue measuring 2.5 x 2 x 1.5 cm. The external surface of this nodule shows grossly normal appearing fatty tissue with focal fibrotic change. There are no orientating features to the specimen. The external surface of the specimen is inked in blue. The specimen is bisected and submitted in toto in cassettes A1 and A2.

Container B is labelled INTERNAL ABDOMINAL WALL OLD LAPAROSCOPIC PORT TUMOUR NODULE and consists of a tan-yellow fragment of soft tissue measuring 3 x 2.5 x 1.2 cm in size. The external aspect of the nodule shows fibrofatty tissue with focal irregularity. There are no orientating features to the specimen. The external aspect of the specimen is inked in blue. The specimen shows a white fibrous firm area that extends to the surface of the specimen. The specimen is submitted in toto in cassettes B1 and B2.

Container C is labelled UTERUS PLUS CERVIX PLUS LEFT TUBE PLUS LEFT OVARY and consists of a 174.5 g total hysterectomy and left salpingo-oophorectomy specimen with a uterus (including cervix) that measures approximately 8.5 cm superior-inferior, 5.5 cm left-right and 5.2 cm anterior-posterior that contains a 2.5 cm long cervix with an exocervix diameter of 2.6 cm, a left fallopian tube that measures 5 x 0.6 cm, and a left ovary that measures 3.5 x 3 x 2 cm in size. The mucosa of the exocervix appears unremarkable grossly. The parametrial resection margin shows normal appearing soft tissue and is inked in black. The serosal surface of the anterior peritoneal reflection of the uterus shows patches of serosal irregularity highly suspicious for tumour involvement, and this involves an area that spans 4.5 x 2.5 cm. The remaining serosal surface of the uterus, including the posterior cul-de-sac, shows only focal mild erythema with no gross evidence of tumour involvement. The surface of the left ovary shows focal irregularity but is predominantly smooth in appearance. A portion of the left ovary is sampled for Tumour Bank. The adventitial surface of the left fallopian tube is unremarkable grossly.

The uterus is bivalved showing a 3 x 0.7 cm endocervical canal that appears unremarkable grossly. The endometrial cavity measures 3.5 cm superior-inferior, 2.5 cm cornu-cornu and has a slightly thickened endometrial lining that measures 0.3 cm in average thickness. No mass lesion is identified. The uterine wall is serially sectioned showing no gross abnormalities. The left ovary is serially sectioned showing multiple 0.5-1 cm coalescing cortical white fibrous nodules. These nodules coalesce to involve an area that measures about 3 cm in maximal size. The fallopian tube is serially sectioned showing no evidence of tumour involvement grossly. Representative sections of the specimen are submitted as follows:

C1 -posterior cul-de-sac

[page 4 of 4]
C2-C3 -anterior cervix and anterior lower uterine segment (contiguous sections)
C4-C5 -posterior cervix and posterior lower uterine segment (contiguous sections)
C6 -anterior endomyometrium
C7-C8 -posterior endomyometrium (inner and outer half)
C9-C12 -sections of the left ovary with a fragment of uninvolved ovarian parenchyma in C12
C13-C14 -left fallopian tube with fimbriated end in C13

Container D is labelled BIOPSY OF RIGHT IP LIGAMENT and consists of two fragments of tan-brown tissue measuring 2 cm and 1.6 cm in size, respectively. The two fragments are submitted in cassettes D1 and D2 in toto, with the larger fragment in D1.

Container E is labelled OMENTUM and consists of a 158 g omentectomy specimen measuring 24 x 11 x 2 cm in size. The omentum contains multiple palpable firm nodules that range in size from 2-4 cm. Serial sectioning of the omentum shows multiple solid white tan stellate shaped nodules. Representative sections of the omentum are submitted in cassettes E1-E5.

Source: NCI Genomic Data Commons file 1dd9cdf3-2592-4706-98db-5acf37d04bfb (TCGA-36-2538.E78DD67E-58F2-4B75-B3A5-1CA9EE6E01E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).